Somatic mutation profile of tumor specimen TARGET-20-PARLMY-09A (aliquot TARGET-20-PARLMY-09A-01D) from TARGET case TARGET-20-PARLMY, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.0 years (2,904 days).
Specimen TARGET-20-PARLMY-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 459b2faa-f3d8-4ae2-889d-ec2ba9ff4f79.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARLMY-10A (Blood Derived Normal), aliquot TARGET-20-PARLMY-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e181cbfe-f2de-488e-96f3-146784874142

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.2446G>C p.D816H | Missense Mutation (SNP) | VAF 83/194 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as rs121913506, COSV55386862, COSV55387240, COSV55408330; ClinVar: likely pathogenic / other / pathogenic; called by muse, mutect2, varscan2
- PTPRT | c.370G>A p.V124M | Missense Mutation (SNP) | VAF 64/137 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV61974113, COSV61985449, COSV62035189; called by muse, mutect2, varscan2
